CPTAC case C3N-03088 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3bbefb92-0868-42e2-962f-be22b354f155

Demographics
Sex at birth: female; Race: asian; Year of birth: 1986; Vital status: Dead; Days to death: 142 days; Year of death: 2018; Country of birth: China.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Occipital lobe; Age at diagnosis: 31.7 years (11,589 days); Year of diagnosis: 2018; Last known disease status: Tumor free; Days to last known disease status: 142 days; Progression or recurrence: no; Days to last follow up: 27 days.
   Pathology details: Greatest tumor dimension: 3.8 cm.

Follow-up (1 entry)
- Days to follow up: 27 days; Disease response: Tumor Free; Karnofsky performance status: 0; ECOG performance status: 4.

Other clinical attributes
- Weight: 46 kg; Height: 153 cm; BMI: 19.65.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-03088-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Occipital Cortex; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -6 days; Initial weight: 368 mg; Time between excision and freezing: 13 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-03088-21: Section location: Occipital Lobe; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-03088-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -6 days; Method of sample procurement: Blood Draw.
